Somatic mutation profile of tumor specimen TCGA-CG-4475-01A (aliquot TCGA-CG-4475-01A-01D-1158-08) from TCGA case TCGA-CG-4475, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.8 years (28,065 days).
Specimen TCGA-CG-4475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f31ef5b3-420a-4e6f-b6d9-0e3473d41c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4475-10A (Blood Derived Normal), aliquot TCGA-CG-4475-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f3a28f2-be04-4b4b-bfd8-a73a66aa50b6

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 3, In Frame Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.3310C>G p.P1104A | Missense Mutation (SNP) | VAF 153/256 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64212669; called by muse, mutect2, varscan2
- ASH1L | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 264/562 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as COSV64212673; called by mutect2, varscan2
- ASPG | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV101496390; called by muse, mutect2
- ATP2C1 | c.1738A>G p.I580V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as rs1282232888, CM020634, COSV60761618; called by muse, mutect2, varscan2
- C11orf87 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV59358210; called by muse, mutect2, varscan2
- COL3A1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1186071837, COSV58595248; called by muse, mutect2, varscan2
- CPAMD8 | c.3808C>T p.R1270C (on ENST00000651564; = p.R1223C on NM_015692.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs779294937, COSV71597277; called by muse, mutect2, varscan2
- CSMD3 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs867604124, COSV52292339; called by muse, mutect2
- ESD | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66340716; called by muse, mutect2, varscan2
- ESPL1 | c.2474C>T p.T825I | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1358715142, COSV57762231; called by muse, mutect2, varscan2
- FLG | c.3490A>C p.T1164P | Missense Mutation (SNP) | VAF 100/1324 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV64237791; called by muse, mutect2
- GJA10 | c.1511C>G p.P504R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.505); catalogued as COSV65356006; called by muse, mutect2, varscan2
- GRID2 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs760655946, COSV56184633; called by muse, mutect2, varscan2
- GSN | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs755630687, COSV58000754; called by muse, mutect2, varscan2
- HMGCS1 | c.1145C>G p.T382S | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV57291323; called by muse, mutect2, varscan2
- KAT6B | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1564632292, COSV54753335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs765184193; called by pindel, varscan2
- MYH3 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as rs1182023838, COSV56865459; called by muse, mutect2, varscan2
- NGFR | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.482); catalogued as rs777677789, COSV99412870; called by muse, mutect2, varscan2
- NRXN1 | c.2774C>A p.T925N | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV58485512; called by muse, mutect2, varscan2
- OSGIN2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 100/543 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1202571003, COSV52411268; called by muse, mutect2, varscan2
- PEG10 | c.595G>A p.E199K (on ENST00000482108 / NM_001040152.2; = p.E233K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/1094 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV71788029; called by muse, mutect2
- POMP | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV66482009; called by muse, mutect2, varscan2
- PRPH | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs767054458, COSV57679567, COSV99142114; called by muse, mutect2, varscan2
- PTPRK | c.3733A>T p.I1245F (on ENST00000368215 / NM_001291984.2; = p.I1246F on NM_002844.4) | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63905264; called by muse, mutect2, varscan2
- RTF1 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV67478813; called by muse, mutect2, varscan2
- SIPA1L2 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53392911, COSV53398082; called by muse, mutect2
- SPRY4 | c.230C>T p.T77M (on ENST00000434127 / NM_001127496.3; = p.T100M on NM_030964.4) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774674946, CM133830, COSV59986194; called by muse, mutect2, varscan2
- SRSF11 | c.1421A>G p.D474G | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV63937667; called by muse, mutect2, varscan2
- TEX15 | c.7450T>A p.S2484T (on ENST00000256246; = p.S2867T on NM_001350162.2) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.295); catalogued as COSV56352370; called by muse, mutect2, varscan2
- TFB2M | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63621002; called by muse, mutect2, varscan2
- TTI1 | c.3039T>G p.I1013M | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV65063064; called by muse, mutect2, varscan2
- URM1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100864887; called by muse, mutect2, varscan2
- UTP20 | c.4628C>T p.T1543I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs1447512117, COSV55384061; called by muse, mutect2, varscan2
- WDR35 | c.2479C>T p.R827W (on ENST00000345530 / NM_001006657.2; = p.R816W on NM_020779.4) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs374027943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFC3H1 | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV66435381; called by muse, mutect2, varscan2
- ZNF283 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs778024301, COSV61032483; called by muse, mutect2, varscan2
- ZNF530 | c.884A>C p.Y295S | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60532353; called by muse, mutect2, varscan2
- CCDC34 | c.146_174del p.R49Lfs*20 | Frame Shift Del (DEL) | VAF 12/131 reads (9%) | called by mutect2, pindel
- NUDT17 | c.448_449delinsG p.H150Afs*23 | Frame Shift Del (DEL) | VAF 30/200 reads (15%) | called by pindel, varscan2*
- ORAI1 | c.337_342del p.H113_D114del | In Frame Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- SHARPIN | c.542_545delinsTGG p.R181Lfs*25 | Frame Shift Del (DEL) | VAF 36/171 reads (21%) | called by pindel, varscan2*
- CAPN12 | c.990C>G p.L330= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV61018140; called by muse, mutect2, varscan2
- DPM1 | c.273A>G p.P91= | Silent (SNP) | VAF 61/260 reads (23%) | catalogued as rs766462970, COSV65373691; ClinVar: likely benign; called by muse, varscan2
- FAT2 | c.3654G>T p.G1218= | Silent (SNP) | VAF 66/191 reads (35%) | catalogued as COSV55827758; called by muse, mutect2, varscan2
- MAP3K4 | c.1179C>T p.L393= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as COSV62337566; called by muse, mutect2, varscan2
- MTNR1B | c.60G>A p.P20= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs777163058, COSV57066862; called by muse, mutect2, varscan2
- MTRR | c.18G>T p.V6= | Silent (SNP) | VAF 72/358 reads (20%) | catalogued as COSV52946327; called by muse, mutect2, varscan2
- NOTCH4 | c.3024C>T p.D1008= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs776017114, COSV66683276; called by muse, mutect2
- PCDHGA10 | c.252C>T p.R84= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as COSV54015306; called by muse, mutect2, varscan2
- TSHZ2 | c.2841T>G p.S947= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as COSV61590959; called by muse, mutect2, varscan2
- TTN | c.32796T>C p.P10932= (on ENST00000591111; = p.P10005= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as COSV60289494; called by muse, mutect2, varscan2
- VPS13B | c.6054A>T p.I2018= | Silent (SNP) | VAF 22/241 reads (9%) | catalogued as COSV62154386; called by muse, mutect2
- ZFPM2 | c.3096G>A p.L1032= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV65875477; called by muse, mutect2, varscan2
- ZNF133 | c.1935G>A p.G645= (on ENST00000316358 / NM_001352454.2; = p.G644= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV60367946; called by muse, mutect2, varscan2
- ZNF658B | n.1822C>T | RNA (SNP) | VAF 8/57 reads (14%) | catalogued as rs1349326367; called by mutect2, varscan2
